Gene-level copy-number profile of tumor specimen TARGET-40-PANXSC-01A from TARGET case TARGET-40-PANXSC, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.2 years (5,545 days).
Specimen TARGET-40-PANXSC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.5dc28930-5e83-521f-bc10-e01d8ffd3893.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANXSC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/157169d1-2b61-489f-a6e8-0d0cbb1a44b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,955; copy number 2: 11,474; copy number 3: 25,230; copy number 4: 10,549; copy number 5: 6,008; copy number 6: 1,249; copy number 7: 704; copy number 8: 556; copy number 9: 75; copy number 10: 22; copy number 11: 5; copy number 12: 17; copy number 13: 5; copy number 14: 81; copy number 17: 29; copy number 18: 76; copy number 19: 28; copy number 21: 104; copy number 23: 43; copy number 27: 39.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–9): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,784 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,977,022–23,088,058, 36 genes, copy number 8 (within-gene range 6–8): CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1, MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2.
- chr1:23,670,294–25,240,253, 49 genes, copy number 9: AL451000.1, RPL11, ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1, IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, AL031432.4, AL031432.5.
- chr1:25,247,837–25,248,321, 1 gene, copy number 9: AL031432.3.
- chr1:25,336,429–30,757,774, 193 genes, copy number 7–10 (broad region; genes not listed).
- chr1:32,862,268–33,512,743, 27 genes, copy number 8: FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1.
- chr1:58,228,682–58,931,897, 14 genes, copy number 7: AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777.
- chr1:58,999,676–59,000,494, 1 gene, copy number 7: PHBP3.
- chr1:66,812,885–72,753,772, 79 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:72,979,014–83,166,815, 123 genes, copy number 7–14 (broad region; genes not listed).
- chr1:84,999,147–85,133,138, 1 gene, copy number 7 (within-gene range 5–7): DNAI3.
- chr1:85,133,794–86,500,259, 25 genes, copy number 7–12: MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6, COL24A1, RNA5SP51, AC104455.1, LINC02795, ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1.
- chr2:102,714,630–104,722,966, 27 genes, copy number 8–10 (within-gene range 5–10): MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27.
- chr2:105,744,912–106,368,876, 13 genes, copy number 7 (within-gene range 5–7): NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1.
- chr2:153,871,922–155,664,668, 19 genes, copy number 8 (within-gene range 3–8): GALNT13, PHBP4, AC009227.1, AC009227.2, RNA5SP107, AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1.
- chr2:223,498,773–223,510,933, 2 genes, copy number 7: AC013448.1, AC013448.2.
- chr4:54,221,126–54,446,723, 5 genes, copy number 8: RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1.
- chr4:68,509,441–68,568,527, 2 genes, copy number 7: UGT2B29P, UGT2B17.
- chr5:121,961,975–122,479,087, 12 genes, copy number 9–13 (within-gene range 3–13): SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805.
- chr5:139,684,645–139,844,466, 6 genes, copy number 7: AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4, PSD2.
- chr5:139,848,290–139,856,389, 1 gene, copy number 7: AC008667.2.
- chr6:24,667,035–25,042,170, 10 genes, copy number 7 (within-gene range 4–7): ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2.
- chr14:48,045,481–48,341,332, 5 genes, copy number 8: AL359212.1, AL512358.1, AL512358.2, AL358335.3, RNU6-297P.
- chr14:105,785,505–106,335,613, 95 genes, copy number 7 (broad region; genes not listed).
- chr15:77,613,027–77,820,900, 1 gene, copy number 7 (within-gene range 3–7): LINGO1.
- chr15:77,784,610–80,252,213, 85 genes, copy number 7–9 (broad region; genes not listed).
- chr15:80,344,853–101,933,350, 532 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr16:77,590,806–77,610,681, 1 gene, copy number 7: LINC02131.
- chr17:15,502,264–15,563,595, 1 gene, copy number 13 (within-gene range 2–13): TVP23C.
- chr17:15,530,773–20,009,234, 255 genes, copy number 13–21 (within-gene range 13–29) (broad region; genes not listed).
- chr17:20,056,287–20,112,990, 2 genes, copy number 14: AC005730.1, KCTD9P1.
- chr19:27,638,483–34,359,412, 143 genes, copy number 14–27 (broad region; genes not listed).
- chr21:38,155,549–38,333,421, 6 genes, copy number 8 (within-gene range 3–8): KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423.
- chr22:24,011,192–24,495,074, 12 genes, copy number 7 (within-gene range 5–7): CABIN1, AC253536.3, SUSD2, GGT5, GGTLC4P, POM121L9P, BCRP1, AP000354.1, SPECC1L, SPECC1L-ADORA2A, ADORA2A, ADORA2A-AS1.

Autosomal genes at a single copy (total copy number 1): 1,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
